TCGA case TCGA-KL-8336 — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/63643ba6-bed9-4c36-91dd-a18105fadc06

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Dead; Days to death: 920 days (2.5 years).

Diagnoses (5)
1. Renal cell carcinoma, chromophobe type (the primary disease): ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 51.5 years (18,821 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 26.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Days to treatment start: 138 days; Days to treatment end: 559 days (1.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temsirolimus; Days to treatment start: 558 days (1.5 years); Days to treatment end: 817 days (2.2 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Days to treatment start: 824 days (2.3 years); Days to treatment end: 838 days (2.3 years).
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Renal cell carcinoma, chromophobe type). Age at diagnosis: 51.7 years (18,868 days); Days to diagnosis: 47 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 82 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.
3. Metastasis of diagnosis 1 (Renal cell carcinoma, chromophobe type). Age at diagnosis: 51.8 years (18,924 days); Days to diagnosis: 103 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 118 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 53.1 years (19,386 days); Days to diagnosis: 565 days (1.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 53.8 years (19,638 days); Days to diagnosis: 817 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Day 47 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 47 days.
- Day 103 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 103 days.
- Day 565 (post initial treatment): Progression or recurrence: Yes.
- Day 817 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 920 days (2.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- Leukocytes: Normal.
- Calcium: Low.
- Platelets: Low.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KL-8336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-KL-8336-01A-01-BS1: Section location: Bottom; Percent tumor cells: 84; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 15; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide TCGA-KL-8336-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KL-8336-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KL-8336-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 1.1; Shortest dimension: 0.3.
  Slide TCGA-KL-8336-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lymph nodes examined: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Tobacco smoking history indicator: 1.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 920 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 920 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 47 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KL-8336-01A-11D-2308-01): tumor purity 0.85, ploidy 1.54, whole-genome doublings 0.
